Somatic mutation profile of tumor specimen MP2PRT-PAVKAE-TMP1-A (aliquot MP2PRT-PAVKAE-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVKAE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,414 days).
Specimen MP2PRT-PAVKAE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18595658-8fe7-4fcd-8962-dcb4bbf641ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVKAE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVKAE-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/854aae92-6457-4a9c-a411-40db9609e026

The open-access MAF lists 25 somatic variants for this specimen: 14 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 8, Nonsense Mutation 2, Intron 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL772284.1 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 22/853 reads (3%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.972); catalogued as rs1386100688; called by muse, mutect2
- ARHGEF10L | c.1554G>C p.K518N | Missense Mutation (SNP) | VAF 18/568 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1557865678; called by muse, mutect2
- CDH11 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 55/387 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs781127265, COSV51756103, COSV51770009, COSV99216980; called by muse, mutect2, varscan2
- MAP1B | c.6682G>A p.E2228K | Missense Mutation (SNP) | VAF 82/633 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV57095437; called by muse, mutect2, varscan2
- METTL11B | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 65/228 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV63029895; called by muse, mutect2, varscan2
- NPAS4 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 119/359 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.059); catalogued as rs765449671, COSV60648925; called by muse, mutect2, varscan2
- SLFN14 | c.1316C>G p.S439C | Missense Mutation (SNP) | VAF 120/386 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV70570308; called by muse, mutect2, varscan2
- TRPV3 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 114/285 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1394145267; called by muse, mutect2, varscan2
- ZNF239 | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 164/454 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748946596, COSV60018947; called by muse, mutect2, varscan2
- LRRK1 | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 73/291 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- RABL6 | c.1739C>A p.S580* | Nonsense Mutation (SNP) | VAF 44/347 reads (13%) | called by muse, mutect2, varscan2
- SMG1 | c.10544C>G p.S3515* | Nonsense Mutation (SNP) | VAF 25/228 reads (11%) | called by muse, mutect2, varscan2
- TRIM33 | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 179/546 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZFP91 | c.1588G>C p.A530P | Missense Mutation (SNP) | VAF 53/518 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- AJM1 | c.2217C>T p.I739= | Silent (SNP) | VAF 75/726 reads (10%) | catalogued as rs887167830, COSV56034445, COSV56034782; called by muse, mutect2, varscan2
- AJM1 | c.2736C>T p.F912= | Silent (SNP) | VAF 80/687 reads (12%) | catalogued as rs773427299; called by muse, mutect2, varscan2
- GPR39 | c.132C>T p.G44= | Silent (SNP) | VAF 67/499 reads (13%) | called by muse, mutect2, varscan2
- KIF21A | c.2682G>A p.T894= (on ENST00000361418 / NM_001378440.1; = p.T881= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 81/334 reads (24%) | catalogued as rs781262318, COSV62768358, COSV62776680; called by muse, mutect2, varscan2
- MAMDC4 | c.513G>A p.Q171= | Silent (SNP) | VAF 50/472 reads (11%) | called by muse, mutect2, varscan2
- MAMDC4 | c.1215G>A p.Q405= | Silent (SNP) | VAF 74/601 reads (12%) | catalogued as rs773469370, COSV99915817; called by muse, mutect2, varscan2
- SULT1C3 | c.297A>G p.K99= | Silent (SNP) | VAF 89/259 reads (34%) | called by muse, mutect2, varscan2
- TMEM238L | c.171C>T p.L57= | Silent (SNP) | VAF 59/577 reads (10%) | called by muse, mutect2
- FSD2 | chr15:82750724 C>G | 3'Flank (SNP) | VAF 68/480 reads (14%) | called by muse, varscan2
- RABL6 | c.705+1571C>T | Intron (SNP) | VAF 32/326 reads (10%) | catalogued as rs1303173507; called by muse, mutect2
- RABL6 | c.*257C>T | 3'UTR (SNP) | VAF 96/613 reads (16%) | catalogued as rs779079178; called by muse, mutect2, varscan2
